Somatic mutation profile of tumor specimen 0DWD2F from CCDI case PBCNSE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.6 years (4,221 days).
Specimen 0DWD2F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8428cd84-8cf7-4fb5-b8ff-be964715c0b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWD1N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3b7b250-028c-499e-88ad-39085701ee89

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Intron 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.3675C>G p.Y1225* | Nonsense Mutation (SNP) | VAF 199/453 reads (44%) | catalogued as rs184830847, COSV104413795, COSV58622516; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDC45 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 67/504 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1324368416, COSV99596943; called by muse, mutect2, varscan2
- CSMD3 | c.6911C>T p.P2304L (on ENST00000297405 / NM_001363185.1; = p.P2200L on NM_052900.3) | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1482005030, COSV52116011; called by muse, mutect2, varscan2
- WDFY3 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 70/385 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55705255; called by muse, mutect2, varscan2
- BZW1 | c.1002A>T p.Q334H | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SIDT1 | c.820T>A p.S274T | Missense Mutation (SNP) | VAF 88/370 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SNRPN | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2
- TNRC6B | c.3621A>T p.Q1207H (on ENST00000454349 / NM_001162501.2; = p.Q1097H on NM_015088.3) | Missense Mutation (SNP) | VAF 54/582 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TTLL5 | c.616T>G p.L206V | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ZFP36L2 | c.1234C>G p.P412A | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF786 | c.1738C>T p.L580F | Missense Mutation (SNP) | VAF 111/217 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASPSCR1 | c.1518C>A p.A506= | Silent (SNP) | VAF 84/534 reads (16%) | called by muse, mutect2, varscan2
- EFHB | c.1134C>T p.G378= | Silent (SNP) | VAF 76/288 reads (26%) | called by muse, mutect2, varscan2
- LDHAL6A | c.528A>G p.Q176= | Silent (SNP) | VAF 188/417 reads (45%) | called by muse, mutect2, varscan2
- LYST | c.24G>A p.L8= | Silent (SNP) | VAF 66/188 reads (35%) | called by muse, mutect2, varscan2
- NLRP8 | c.2346G>A p.V782= | Silent (SNP) | VAF 34/217 reads (16%) | catalogued as rs775812878; called by mutect2, varscan2
- SSTR5 | c.864C>T p.F288= | Silent (SNP) | VAF 65/252 reads (26%) | catalogued as rs369091976, COSV53512910; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3095G>T | Intron (SNP) | VAF 90/305 reads (30%) | called by muse, mutect2, varscan2
- INTS8 | c.2871+41G>T | Intron (SNP) | VAF 98/205 reads (48%) | called by muse, mutect2, varscan2
- RCBTB2 | c.-103T>G | 5'UTR (SNP) | VAF 57/319 reads (18%) | called by muse, mutect2, varscan2
